Somatic mutation profile of tumor specimen TCGA-A2-A25B-01A (aliquot TCGA-A2-A25B-01A-11D-A167-09) from TCGA case TCGA-A2-A25B, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 39.6 years (14,454 days).
Specimen TCGA-A2-A25B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3247ac91-e5f4-497e-94e0-bb2ae9bfca1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A25B-10A (Blood Derived Normal), aliquot TCGA-A2-A25B-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04259b6e-cd37-49ed-b080-49df301a53a7

The open-access MAF lists 105 somatic variants for this specimen: 78 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 24, Frame Shift Del 5, Splice Site 3, Nonsense Mutation 3, RNA 1, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 33/42 reads (79%) | catalogued as rs80356875, CM990288, COSV58797263; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GATA3 | c.1198_1199del p.M400Vfs*106 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1085307641, COSV60521761; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA9 | c.4561A>G p.K1521E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60629844; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3699G>C p.L1233F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV54465059; called by muse, mutect2
- AGBL5 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59937907; called by muse, mutect2, varscan2
- ALG10B | c.1177A>T p.I393F | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV58142633; called by muse, mutect2, varscan2
- ALPK2 | c.99C>G p.C33W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100864223; called by muse, mutect2
- APOB | c.7482T>G p.N2494K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV51948949; called by muse, mutect2, varscan2
- ARHGAP31 | c.3524G>A p.R1175H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1020868632, COSV51792219, COSV51797736; called by muse, mutect2, varscan2
- ASNS | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51555339; called by muse, mutect2, varscan2
- ATP2A1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750049229, COSV63922116; called by muse, mutect2, varscan2
- BLK | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52055515, COSV52055587; called by muse, mutect2, varscan2
- C2CD5 | c.1976C>G p.S659* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV61727127; called by muse, mutect2, varscan2
- CARD17 | c.14T>A p.V5D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV65215527; called by muse, mutect2, varscan2
- CHST9 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52446957; called by muse, mutect2, varscan2
- COL6A6 | c.6331C>G p.Q2111E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs1466644271, COSV62034729; called by muse, mutect2, varscan2
- DTX4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1423783336, COSV57091470, COSV57092379; called by muse, mutect2, varscan2
- DUSP19 | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV61193855; called by muse, mutect2, varscan2
- ENPP1 | c.2351A>G p.Y784C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62935423; called by muse, mutect2, varscan2
- ESPL1 | c.5140G>T p.A1714S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99229057; called by muse, mutect2
- FAM13C | c.1010G>C p.R337P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53254588; called by muse, mutect2, varscan2
- FAP | c.140T>A p.I47N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV51866524; called by muse, mutect2, varscan2
- FOLH1 | c.2063+1G>C p.X688_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99922918, COSV99923424; called by muse, mutect2, varscan2
- GAPDH | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); catalogued as COSV57521933; called by muse, mutect2, varscan2
- GLIPR1L1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157503; called by muse, mutect2
- GPR12 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV67344801; called by muse, mutect2
- H2BC11 | c.178A>C p.M60L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV60362630; called by muse, mutect2, varscan2
- HYDIN | c.7518G>T p.R2506S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV59267416; called by muse, mutect2, varscan2
- ITPRID2 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV57475616; called by muse, mutect2, varscan2
- KIAA1109 | c.7273G>T p.E2425* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99149951; called by muse, mutect2
- KIAA1109 | c.7274A>C p.E2425A | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV52688551; called by muse, mutect2, varscan2
- KIAA1217 | c.4831G>T p.D1611Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56822055; called by muse, mutect2, varscan2
- KMT2D | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV56480641; called by muse, mutect2, varscan2
- KRT4 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV53409315; called by muse, mutect2
- LOXL4 | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369951896; called by muse, mutect2
- MXRA5 | c.4475C>G p.A1492G | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV99476184; called by muse, mutect2, varscan2
- NFASC | c.1105C>A p.Q369K (on ENST00000339876 / NM_001378329.1; = p.Q380K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV58377020; called by muse, mutect2
- NPAS2 | c.1476G>C p.M492I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV59561369; called by muse, mutect2, varscan2
- NRK | c.3280C>A p.P1094T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54604713; called by muse, mutect2, varscan2
- PCDHGA1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs1344067004, COSV65298800; called by muse, mutect2, varscan2
- PDCL | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52343382; called by muse, mutect2, varscan2
- PLA2G4D | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51823049; called by muse, mutect2, varscan2
- PMP2 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV56267778; called by muse, mutect2, varscan2
- PRKCE | c.1438-1G>A p.X480_splice | Splice Site (SNP) | VAF 12/67 reads (18%) | catalogued as COSV60327458; called by muse, mutect2, varscan2
- PROX1 | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.029); catalogued as COSV54782738; called by muse, mutect2
- PSG2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.41); catalogued as COSV68885188; called by muse, mutect2, varscan2
- RAB33A | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57062996, COSV57063117; called by mutect2, varscan2
- RBM27 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs749571390, COSV54593433; called by muse, mutect2, varscan2
- RPA2 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV57878663; called by muse, mutect2, varscan2
- RYR1 | c.7483G>A p.V2495M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs200291321, COSV62107905; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs373326624, COSV63684169, COSV63713339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as rs1262133916, COSV53525184; called by muse, mutect2
- SLC22A14 | c.265T>A p.F89I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56199052; called by muse, mutect2, varscan2
- SLC2A2 | c.24del p.T9Pfs*22 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs766082034, COSV58585924, COSV58588169; called by mutect2, pindel, varscan2
- SLC30A1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65361501; called by muse, mutect2
- SLC39A12 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV101070094, COSV66201781; called by muse, mutect2
- SLC9C1 | c.951T>A p.H317Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.185); catalogued as COSV59886138, COSV59892092; called by muse, mutect2, varscan2
- SMAD4 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100747568, COSV61685097; called by muse, mutect2, varscan2
- SMARCA1 | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64411432, COSV64413137; called by muse, mutect2, varscan2
- TARS2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV64696677; called by muse, mutect2, varscan2
- TBC1D4 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs544873334, COSV66491240; called by mutect2, varscan2
- TENM4 | c.6389T>C p.I2130T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53661736; called by muse, mutect2, varscan2
- TG | c.3133G>A p.G1045R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1320164743, COSV55090853; called by muse, mutect2, varscan2
- TG | c.5223G>C p.Q1741H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55090863; called by muse, mutect2, varscan2
- TMED2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs1162918031, COSV51630106; called by muse, mutect2, varscan2
- TMEM87A | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67747903; called by muse, mutect2, varscan2
- TMOD3 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV57945827; called by muse, mutect2, varscan2
- TTN | c.91159G>T p.A30387S (on ENST00000591111; = p.A22963S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | PolyPhen benign (0.41); catalogued as COSV100627628, COSV60284178; called by muse, mutect2, varscan2
- UGDH | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV57099549; called by muse, mutect2, varscan2
- ZNF544 | c.1447A>G p.K483E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV54138080; called by muse, mutect2, varscan2
- ZNF711 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52158092; called by muse, mutect2
- ZNF831 | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV100925875; called by muse, mutect2
- GLDC | c.3031_3032dup p.F1012Hfs*20 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- NUP54 | c.1331_1332del p.F444Wfs*6 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- RBMS1 | c.476del p.N159Ifs*92 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- SERPINA11 | c.918-13_925del p.X306_splice | Splice Site (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- TNFAIP3 | c.286_295del p.K96Vfs*24 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- ZNF44 | c.484_498del p.G162_L166del (on ENST00000356109 / NM_001164276.2; = p.G114_L118del on NM_016264.4 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel
- ABCA13 | c.5373C>T p.F1791= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs368321892; called by muse, mutect2, varscan2
- C7orf33 | c.93G>T p.G31= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV61023779; called by muse, mutect2, varscan2
- CCN4 | c.756C>A p.R252= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51534967; called by mutect2, varscan2
- CRAT | c.1245C>T p.H415= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1259194829, COSV58878831; called by muse, mutect2, varscan2
- DNMT1 | c.414C>T p.P138= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1418913825, COSV61582681; called by muse, mutect2, varscan2
- DOCK6 | c.5346C>T p.I1782= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53920846; called by muse, mutect2, varscan2
- EPHB1 | c.1665C>A p.S555= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV67669164; called by muse, mutect2, varscan2
- EPRS1 | c.4179T>A p.A1393= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as rs1211460298, COSV100859336; called by muse, mutect2
- ERC1 | c.484T>C p.L162= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1449057523, COSV61698624; called by muse, mutect2, varscan2
- FHL1 | c.147G>A p.A49= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1394298803, COSV61782530; called by muse, mutect2, varscan2
- FRY | c.8512C>T p.L2838= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV66511634; called by muse, mutect2, varscan2
- HCRTR1 | c.768G>A p.R256= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV65486436; called by muse, mutect2, varscan2
- IRAK2 | c.1227C>A p.L409= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56529799, COSV56534939; called by muse, mutect2
- KIAA1328 | c.609A>C p.S203= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV54463204; called by muse, mutect2, varscan2
- MAN1A2 | c.1356C>T p.H452= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs776891311, COSV62980828; called by muse, mutect2, varscan2
- MGAT5 | c.2061C>T p.A687= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56100193; called by muse, mutect2, varscan2
- OR4N5 | c.357C>G p.A119= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV61321190; called by muse, mutect2, varscan2
- PRPF8 | c.1638G>A p.L546= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59266915; called by muse, mutect2, varscan2
- PRSS55 | c.111A>G p.G37= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60809179; called by muse, mutect2
- PSD3 | c.2442C>A p.T814= (on ENST00000440756; = p.T813= on NM_015310.4) | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV54078466; called by muse, mutect2, varscan2
- RIPK2 | c.456C>T p.I152= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV55134782; called by muse, mutect2, varscan2
- SLC30A8 | c.363G>C p.L121= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV69975074; called by muse, mutect2, varscan2
- SORL1 | c.3828G>A p.T1276= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs536340053, COSV52751791; called by mutect2, varscan2
- ZNF524 | c.387G>A p.L129= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV55608972; called by muse, mutect2
- ATP2B3 | c.3342+4569C>A | Intron (SNP) | VAF 21/121 reads (17%) | catalogued as COSV54858695, COSV99684773; called by muse, mutect2, varscan2
- LINC02145 | n.178T>A | RNA (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- TPD52L3 | chr9:6330991 A>C | 3'Flank (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100095931; called by muse, mutect2
